Somatic mutation profile of tumor specimen C3L-01064-01 (aliquot CPT0113430010) from CPTAC case C3L-01064, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G2; Age at diagnosis: 54.8 years (20,028 days).
Specimen C3L-01064-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 22bf40cc-a21f-4dec-9a73-620282f7af00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01064-31 (Blood Derived Normal), aliquot CPT0114370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/febacba3-43b2-4012-9659-ef6514210104

The open-access MAF lists 93 somatic variants for this specimen: 67 protein-altering or splice-affecting, 19 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 19, Intron 6, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 2, Frame Shift Del 2, Splice Region 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 81/352 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28931589, COSV62687976, COSV62688267, COSV62692205; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 19/69 reads (28%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.209+2dup p.X70_splice | Splice Site (INS) | VAF 26/58 reads (45%) | hotspot (GDC flag); catalogued as rs1064794925; ClinVar: likely pathogenic; called by pindel, varscan2
- ATP10B | c.3085C>T p.R1029C | Missense Mutation (SNP) | VAF 80/252 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370967558; called by muse, mutect2, varscan2
- ATXN7L2 | c.1333C>T p.R445W | Missense Mutation (SNP) | VAF 61/229 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs770557237, COSV60205147; called by muse, mutect2, varscan2
- C12orf40 | c.1671C>G p.F557L | Missense Mutation (SNP) | VAF 16/239 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV61129168; called by muse, mutect2
- CCDC166 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 52/232 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs1488788057; called by muse, mutect2
- CCDC183 | c.1278+6G>A | Splice Region (SNP) | VAF 136/430 reads (32%) | catalogued as rs944334790; called by muse, mutect2, varscan2
- CHD5 | c.559G>A p.V187I | Missense Mutation (SNP) | VAF 20/319 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.039); catalogued as rs866020323, COSV52412320; called by muse, mutect2
- CTU1 | c.544A>G p.M182V | Missense Mutation (SNP) | VAF 22/597 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as rs1318479749; called by muse, mutect2
- DUS3L | c.590C>T p.A197V | Missense Mutation (SNP) | VAF 22/509 reads (4%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs778109870; called by muse, mutect2
- EMSY | c.3022C>T p.Q1008* | Nonsense Mutation (SNP) | VAF 109/459 reads (24%) | catalogued as COSV100595810; called by muse, mutect2, varscan2
- EPB41L3 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs757841955, COSV59465043; called by muse, mutect2, varscan2
- FAM161A | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 8/200 reads (4%) | catalogued as COSV100281380, COSV56766208; called by muse, mutect2
- FAM47C | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 40/843 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as rs1417215508; called by muse, mutect2
- FRMPD3 | c.4795C>T p.R1599C | Missense Mutation (SNP) | VAF 16/415 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1386662974; called by muse, mutect2
- GLRB | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as rs141265285; called by muse, mutect2, varscan2
- GLYR1 | c.1141C>T p.R381C | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1330895855, COSV58927055; called by mutect2, varscan2
- HHIPL1 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV58090541, COSV58092124; called by muse, mutect2
- IGFN1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 40/422 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV55186051; called by muse, mutect2, varscan2
- ILDR1 | c.970G>A p.V324I (on ENST00000344209 / NM_001199799.2; = p.V280I on NM_175924.4) | Missense Mutation (SNP) | VAF 40/196 reads (20%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1250966459, COSV99877890; called by muse, mutect2, varscan2
- KIAA0100 | c.3211G>A p.V1071M | Missense Mutation (SNP) | VAF 62/210 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.836); catalogued as rs1286899600; called by muse, mutect2, varscan2
- KLK9 | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99143981; called by muse, mutect2, varscan2
- LYST | c.6304C>T p.R2102C | Missense Mutation (SNP) | VAF 93/469 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as rs1164812258; called by muse, mutect2, varscan2
- NT5C2 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 13/366 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260681713; called by muse, mutect2
- PCDHA9 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 23/592 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.057); catalogued as COSV65323912; called by muse, mutect2
- PLXNA2 | c.2455C>T p.R819W | Missense Mutation (SNP) | VAF 165/361 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs533963210, COSV65445865; called by muse, mutect2, varscan2
- PRSS3 | c.356G>T p.G119V (on ENST00000361005 / NM_007343.4; = p.G227V on NM_002771.3) | Missense Mutation (SNP) | VAF 68/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776237099, COSV61554440; called by muse, varscan2
- PTEN | c.29G>A p.S10N | Missense Mutation (SNP) | VAF 106/550 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV64289204, COSV64299108; called by muse, mutect2, varscan2
- RBMXL2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.197); catalogued as rs1289501818, COSV100182023; called by muse, mutect2
- RRAS2 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 102/279 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56329798, COSV56330700, COSV56332575; called by muse, mutect2, varscan2
- RUBCN | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs1185888729, COSV56363848; called by muse, mutect2
- SGPL1 | c.464A>G p.K155R | Missense Mutation (SNP) | VAF 9/206 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1281631258; called by muse, mutect2
- TECTA | c.3098G>A p.R1033Q | Missense Mutation (SNP) | VAF 141/398 reads (35%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.704); catalogued as rs531370547; called by muse, mutect2, varscan2
- TRRAP | c.2281C>T p.R761W | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62847295; called by muse, mutect2, varscan2
- AOC3 | c.1043G>C p.R348T | Missense Mutation (SNP) | VAF 85/534 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARID1A | c.1336dup p.S446Ffs*177 | Frame Shift Ins (INS) | VAF 73/305 reads (24%) | called by mutect2, pindel, varscan2
- B4GALNT3 | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.48); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CCDC88C | c.4570G>A p.A1524T | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2
- CKM | c.163G>T p.D55Y | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- DHRS4 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 42/289 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- FAM155B | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 85/302 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- FAT3 | c.5021_5022del p.K1674Rfs*8 | Frame Shift Del (DEL) | VAF 54/184 reads (29%) | called by mutect2, pindel, varscan2
- FBXL5 | c.1276del p.I426Lfs*25 | Frame Shift Del (DEL) | VAF 46/183 reads (25%) | called by mutect2, pindel, varscan2
- FUNDC2 | c.541G>C p.G181R | Missense Mutation (SNP) | VAF 67/239 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIN2A | c.3769A>G p.T1257A | Missense Mutation (SNP) | VAF 26/694 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.005); called by muse, mutect2
- IGHV2-26 | c.49G>A p.V17I | Missense Mutation (SNP) | VAF 85/297 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.523); called by muse, mutect2, varscan2
- LAMA3 | c.8017G>T p.A2673S (on ENST00000313654 / NM_198129.4; = p.A1064S on NM_000227.6) | Missense Mutation (SNP) | VAF 24/506 reads (5%) | SIFT tolerated (0.5); PolyPhen benign (0.006); called by muse, mutect2
- LMBRD2 | c.1164dup p.L389Tfs*21 | Frame Shift Ins (INS) | VAF 27/109 reads (25%) | called by mutect2, pindel, varscan2
- LONP2 | c.2059G>A p.G687S | Missense Mutation (SNP) | VAF 120/478 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MAGEB3 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 40/180 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- MARCHF10 | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 24/502 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.006); called by muse, mutect2
- NBAS | c.3998C>T p.T1333I | Missense Mutation (SNP) | VAF 9/242 reads (4%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2
- NCBP2L | c.290G>T p.R97L | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.111); called by muse, mutect2
- NIF3L1 | c.436+1G>T p.X146_splice (on ENST00000409020 / NM_001369444.1; = p.X119_splice on NM_021824.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 21/92 reads (23%) | called by muse, mutect2, varscan2
- OR10G4 | c.532T>G p.C178G | Missense Mutation (SNP) | VAF 23/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PALLD | c.1831_1834dup p.G612Efs*14 | Frame Shift Ins (INS) | VAF 44/322 reads (14%) | called by mutect2, varscan2
- PDZRN3 | c.1405C>T p.R469C | Missense Mutation (SNP) | VAF 10/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PIEZO2 | c.7861G>T p.D2621Y | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- PKN1 | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 18/434 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRPF8 | c.3938C>T p.P1313L | Missense Mutation (SNP) | VAF 14/321 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SPIB | c.413G>A p.S138N | Missense Mutation (SNP) | VAF 60/284 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- TFB1M | c.285+6A>C | Splice Region (SNP) | VAF 12/352 reads (3%) | called by muse, mutect2
- TFE3 | c.911A>G p.D304G | Missense Mutation (SNP) | VAF 22/384 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.196); called by muse, mutect2
- TRPM6 | c.2792A>G p.D931G | Missense Mutation (SNP) | VAF 18/616 reads (3%) | SIFT tolerated (0.22); PolyPhen benign (0.014); called by muse, mutect2
- TTC6 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- YAP1 | c.910C>T p.Q304* (on ENST00000282441 / NM_001130145.3; = p.Q266* on NM_006106.5) | Nonsense Mutation (SNP) | VAF 12/310 reads (4%) | called by muse, mutect2
- ABLIM1 | c.1914C>T p.Y638= | Silent (SNP) | VAF 68/132 reads (52%) | catalogued as rs199591198; called by muse, mutect2, varscan2
- B3GNT6 | c.924C>T p.D308= | Silent (SNP) | VAF 14/392 reads (4%) | called by muse, mutect2
- CCDC168 | c.16671G>A p.P5557= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as rs764804992, COSV59424519; called by muse, mutect2, varscan2
- CILP2 | c.2871C>T p.N957= | Silent (SNP) | VAF 10/228 reads (4%) | catalogued as COSV52280368; called by muse, mutect2
- CT47B1 | c.129C>T p.S43= | Silent (SNP) | VAF 184/958 reads (19%) | catalogued as rs769024077, COSV64891004; called by muse, mutect2, varscan2
- DNAH11 | c.11232C>A p.I3744= | Silent (SNP) | VAF 49/310 reads (16%) | catalogued as rs201120788, COSV60966907; called by muse, mutect2, varscan2
- DNAH5 | c.9795G>A p.R3265= | Silent (SNP) | VAF 117/427 reads (27%) | called by muse, mutect2, varscan2
- FGF12 | c.471G>T p.V157= (on ENST00000454309 / NM_021032.5; = p.V95= on NM_004113.6) | Silent (SNP) | VAF 22/169 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.1785T>A p.A595= | Silent (SNP) | VAF 228/949 reads (24%) | called by muse, mutect2, varscan2
- GP6 | c.348C>T p.L116= | Silent (SNP) | VAF 109/563 reads (19%) | called by muse, mutect2, varscan2
- HERC2 | c.1923T>C p.G641= | Silent (SNP) | VAF 6/137 reads (4%) | called by muse, mutect2
- HPS1 | c.303C>T p.S101= | Silent (SNP) | VAF 73/466 reads (16%) | catalogued as rs769932435; called by muse, mutect2, varscan2
- HTT | c.3042C>A p.I1014= | Silent (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- KMO | c.1410C>T p.P470= | Silent (SNP) | VAF 36/378 reads (10%) | catalogued as rs150853900; called by muse, mutect2
- OVOL3 | c.615A>G p.A205= (on ENST00000585332; = p.A181= on NM_001302757.1) | Silent (SNP) | VAF 131/440 reads (30%) | called by muse, mutect2, varscan2
- PTPN6 | c.1503G>A p.T501= | Silent (SNP) | VAF 109/663 reads (16%) | catalogued as rs782495635, COSV59683980; called by muse, mutect2, varscan2
- RNF213 | c.14043C>T p.I4681= | Silent (SNP) | VAF 89/353 reads (25%) | catalogued as COSV100301899; called by muse, mutect2, varscan2
- SND1 | c.699G>A p.R233= | Silent (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- TSPYL6 | c.522G>A p.A174= | Silent (SNP) | VAF 23/453 reads (5%) | catalogued as rs1242105090, COSV57817835; called by muse, mutect2
- ABR | c.1791+18355G>A | Intron (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- C1QTNF1 | c.-14-118G>A | Intron (SNP) | VAF 211/755 reads (28%) | catalogued as rs766692804; called by muse, mutect2, varscan2
- ERO1A | c.676+17C>A | Intron (SNP) | VAF 11/64 reads (17%) | catalogued as rs201842934; called by muse, mutect2, varscan2
- MRC1 | c.917-133dup | Intron (INS) | VAF 22/187 reads (12%) | called by mutect2, varscan2
- PPP1CC | c.56-17C>T | Intron (SNP) | VAF 17/49 reads (35%) | catalogued as rs370380512, COSV100534878; called by muse, mutect2, varscan2
- RETSAT | c.1117+42A>G | Intron (SNP) | VAF 159/609 reads (26%) | catalogued as rs544619588; called by muse, mutect2, varscan2
- ZNF254 | c.-52G>A | 5'UTR (SNP) | VAF 110/492 reads (22%) | called by muse, mutect2, varscan2
